National Lung Screening Trial (NLST) participant 203408 — screening results and CT findings
Open-access record from the public subset of National Lung Screening Trial clinical data distributed by the NCI Imaging Data Commons (release v24, collection nlst). NLST enrolled current and former heavy smokers aged 55–74 in 2002–2004 and randomised them to three annual screens (T0, T1, T2) with low-dose CT or chest radiography, with follow-up through 2009. Coded values are written out from the NLST data dictionaries; day counts are days from randomisation.
https://doi.org/10.7937/TCIA.HMQ8-J677

Participant
Age at randomisation: 55 years; Gender: male; Race: Black or African-American; Cigarette smoking status at randomisation: current smoker; Enrolled through an American College of Radiology Imaging Network (ACRIN) centre (from the participant ID range).

Screening results (official result of each annual screen after comparison with prior images; this participant has CT screening exam records, so these are low-dose CT screens)
- T0 (day 0): Negative screen, no significant abnormalities. Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 120 mA, display field of view 36 cm, reconstruction filter GE Standard.
- T1 (day 349): Positive, no significant change: stable abnormalities potentially related to lung cancer, unchanged since the prior screening exam. Isolation read, before comparison with prior images: positive (nodule(s) >= 4 mm, mass or other suspicious abnormality). Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 120 mA, display field of view 36 cm, reconstruction filter GE Standard / GE, other.
- T2 (day 734): Negative screen, minor abnormalities not suspicious for lung cancer. Isolation read, before comparison with prior images: positive (nodule(s) >= 4 mm, mass or other suspicious abnormality). Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 120 mA, display field of view 36 cm, reconstruction filter GE Standard.

Abnormalities recorded by the reading radiologist on the CT screens (7 abnormalities; numbered within each screening year; size, margins, attenuation and location were collected only for non-calcified nodules or masses of at least 4 mm; interval-change items come from the comparison read)
- T0 abnormality 1: Non-calcified micronodule(s) (opacity < 4 mm diameter).
- T0 abnormality 2: Significant cardiovascular abnormality.
- T1 abnormality 1: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the left lower lobe; longest diameter 5 mm, longest perpendicular diameter 5 mm; margins smooth; predominant attenuation soft tissue; greatest diameter on CT slice 141; pre-existing on earlier images (earliest visible day 0); no interval growth; no suspicious change in attenuation.
- T1 abnormality 2: Non-calcified micronodule(s) (opacity < 4 mm diameter).
- T2 abnormality 1: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the left lower lobe; longest diameter 5 mm, longest perpendicular diameter 5 mm; margins smooth; predominant attenuation soft tissue; greatest diameter on CT slice 125; pre-existing on earlier images (earliest visible day 0); no interval growth; no suspicious change in attenuation.
- T2 abnormality 2: Non-calcified micronodule(s) (opacity < 4 mm diameter).
- T2 abnormality 3: Emphysema.

Follow-up
No confirmed lung cancer during the trial; Last known free of lung cancer: day 1,931.
